Somatic mutation profile of tumor specimen TARGET-10-PARNMV-09A (aliquot TARGET-10-PARNMV-09A-01D) from TARGET case TARGET-10-PARNMV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,481 days).
Specimen TARGET-10-PARNMV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1d0602a-fc49-41d9-acc6-611c6c6dd858.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNMV-14A (Bone Marrow Normal), aliquot TARGET-10-PARNMV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7425c50b-b71b-4284-b775-ff03bc112e44

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Ins 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AUTS2 | c.2956C>T p.R986W | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs748790164, COSV100714568, COSV61416720; called by muse, mutect2, varscan2
- CDKN2A | c.172dup p.R58Pfs*62 | Frame Shift Ins (INS) | VAF 10/12 reads (83%) | catalogued as COSV58691564; called by mutect2, varscan2
- CFH | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 156/322 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as CM100539, COSV66410739; called by muse, varscan2
- CUBN | c.2192C>T p.T731I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs746213558, COSV64709407, COSV64721187; called by muse, mutect2, varscan2
- DMRTC2 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV54187436; called by muse, mutect2
- GPR176 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs777356131, COSV100137143, COSV54443199; called by muse, mutect2, varscan2
- LPAR1 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV62690190; called by muse, mutect2, varscan2
- PAPLN | c.3076G>T p.A1026S (on ENST00000554301; = p.A999S on NM_173462.4) | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs199699862, COSV53720760; called by muse, mutect2, varscan2
- KPNA2 | c.783dup p.H262Sfs*2 | Frame Shift Ins (INS) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- ALS2 | c.4773C>T p.H1591= | Silent (SNP) | VAF 70/167 reads (42%) | catalogued as rs369015911, COSV51886359; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSPA4 | c.1578G>A p.Q526= | Silent (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- LZTS2 | c.1467G>A p.E489= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1162374909; called by muse, mutect2, varscan2
- MTSS1 | c.708G>T p.L236= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs766075010, COSV100275959; called by muse, mutect2, varscan2
- SCN4A | c.4566C>T p.F1522= | Silent (SNP) | VAF 69/162 reads (43%) | catalogued as rs538968877; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC027612.1 | n.1349G>T | RNA (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- MROH9 | c.*16G>A | 3'UTR (SNP) | VAF 25/52 reads (48%) | catalogued as rs190565369, COSV100883117; called by muse, mutect2, varscan2
